Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A7M9, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A7M9-01A (Primary Tumor).

[page 1 of 3]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected		Time Received	
Time Reported		Time Transmitted	
Order Number		Ordering Provider	
Status	Final	Relevant Information	
		Location	
Copied To			
Report Patient	Name:		
Demographics (for verification purposes)	Date of Birth:		
	Sex:		

ICD O-3
Carcinoma, hepatocellular
817013
Site: Liver C22.0
9/25/13

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description
A. Gallbladder
B. Right liver

Clinical Information
Hepatocellular carcinoma.
Infectious patient: No
Immunocompromised: N/A
History of neoplasm: N/A

Diagnosis
A. Gallbladder; Cholecystectomy:
- Cholelithiasis, chronic cholecystitis.

B. Liver, (Right Lobe); Resection:
- Moderately differentiated hepatocellular carcinoma, 11.4 cm, confined within liver capsule, vascular invasion present, resection margin negative for malignancy.
- Iron overload (4+), consistent with history of hemochromatosis.
- Liver cirrhosis.

Reported by:

Electronically signed by:
Verified:

Synoptic Report
Specimen:
Liver
Gallbladder

[page 2 of 3]
PROCEDURE:

Partial hepatectomy

*Major hepatectomy (3 segments or more)

TUMOR SIZE:

Greatest dimension: 11.4 cm

*Additional dimensions: 10.4 x 8.4 cm

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GII: Moderately differentiated

TUMOR EXTENSION (select all that apply):

Tumor confined to liver

PRIMARY TUMOR (pT):

pT3: Multiple tumors more than 5 cm or tumor involving a major branch of the portal or hepatic vein(s)

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 4 mm

*VENOUS (LARGE VESSEL) INVASION (V):

*Present

*ADDITIONAL PATHOLOGIC FINDINGS:

*Cirrhosis/fibrosis

*Iron overload

Gross Description

Received are specimen containers A to B. All requisitions and specimen containers are labelled with the patient's name, The cassettes and are labelled with the Surgical Number

A. The specimen is received fresh and is subsequently placed into formalin. The container is designated as "Gallbladder". The specimen consists of an intact gallbladder which measures 16.5 x 7.5 x 6.5 cm. The serosa is slightly congested but otherwise unremarkable. The adventitial surface is marked with black dye. A cystic duct lymph node is not grossly identified. The cystic duct is patent. The lumen contains yellow, red watery bile and multiple black calculi which range in size from less than 0.1 cm to 1.3 cm in maximum dimension. The calculi are irregular, smooth and multifaceted. The mucosa is green to yellow-stained and velvety. There is an area of defect on the mucosa measuring 0.4 cm in maximum dimension, which comes to within 8.2 cm of the cystic duct margin.

Representative sections are submitted as follows:

A1 - cystic duct margin, neck, body and fundus. The section from the body contains the mucosal defect.

B. The specimen is received fresh and is subsequently placed into formalin. The container is designated as "right liver". The specimen consists of a liver lobe which weighs 770 g and measures 13.0 x 11.7 x 8.6 cm. The cauterized resection margin is marked with black dye. The capsular surface is dark brown to congested with irregular tan areas. Multiple palpable firm nodules are identified on the capsular surface and come to within 2.5 cm of the nearest resection margin. Sectioning through the specimen reveals an ill-defined tan to white to brown, slightly friable mass measuring 11.4 x 10.5 x 8.4 cm. Grossly, this mass extends to the capsular surface. The mass comes grossly to within 0.4 cm of the nearest resection margin. Grossly, it appears as if the tumor has invaded a vessel. The remaining liver parenchyma appears to be dark brown to orange, mottled and firm. The mass is adjacent to the nodule palpated on the capsular surface.

Representative sections are submitted as follows:

[page 3 of 3]
- B1 - most unremarkable liver parenchyma.
B2 - two sections of mass in relation to nearest resection margin.
B3 and B4 - three sections of possible vessel invasion of tumor.
B5 - second area of possible vessel invasion, contiguous section bisected.
B6 - two sections demonstrating possible capsular invasion.
B7 through B9 - three sections of liver which are grossly uninvolved by the mass (? cirrhosis).

Microscopic Description

B. Sections of the tumor show a poorly differentiated hepatocellular carcinoma. Immunohistochemistry yielded the following results: Alpha fetoprotein+, CEA(p)-, EMA canalicular pattern, vimentin-, Hep Par1+.

Accession Number
Encounter Number
Patient Location

diPAA Discrepancy		✓

Source: NCI Genomic Data Commons file 527b7be8-0fe7-4dfa-8189-b31d8cc58ee2 (TCGA-G3-A7M9.0759EEFA-E337-43A5-A6B8-7FDB5FE579EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).